Gene-level copy-number profile of tumor specimen TCGA-AX-A2H4-01A from TCGA case TCGA-AX-A2H4, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 66.3 years (24,234 days).
Specimen TCGA-AX-A2H4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.26eef856-9692-4618-8000-9f5877fe457a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AX-A2H4-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 818 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b63029f9-f9a5-4546-9252-e78758e18766

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 140; copy number 1: 884; copy number 2: 26,336; copy number 3: 18,355; copy number 4: 8,696; copy number 5: 3,292; copy number 6: 1,181; copy number 7: 298; copy number 8: 191; copy number 9: 261; copy number 10: 39; copy number 11: 16; copy number 12: 23; copy number 13: 39; copy number 14: 12; copy number 15: 33; copy number 27: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AX-A2H4-01A-21D-A18N-01): tumor purity 0.56, ploidy 2.85, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 140 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:245,614,773–245,676,478, 2 genes: AC104462.2, AC104462.1.
- chr2:212,795,300–212,832,945, 2 genes: LINC01878, PCED1CP.
- chr4:181,237,358–181,265,145, 2 genes: AC019235.1, LINC02500.
- chr9:77,177,445–77,648,322, 5 genes (within-gene range 0–2): VPS13A, GNA14, GNA14-AS1, NUTF2P3, RNU6-1303P.
- chr12:8,776,219–11,521,686, 129 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,390 genes in 81 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:57,598–15,400,283, 495 genes, copy number 5–6 (within-gene range 2–6) (broad region; genes not listed).
- chr1:40,245,947–41,043,890, 38 genes, copy number 6: TMCO2, AL050341.2, ZMPSTE24, AL050341.1, COL9A2, AL031985.2, SMAP2, AL031985.1, AL031985.4, ZFP69B, AL031985.3, AL603839.4, ZFP69, AL603839.3, EXO5, AL603839.1, AL603839.2, ZNF684, AL356379.2, AL356379.1, GTF2F2P2, RIMS3, AL031289.2, AL031289.1, NFYC-AS1, NFYC, MIR30E, MIR30C1, KCNQ4, RN7SL326P, CITED4, AC119677.1, AL391730.1, AL391730.2, UBE2V1P8, CTPS1, SLFNL1-AS1, SLFNL1.
- chr1:155,745,829–156,192,203, 24 genes, copy number 5: MSTO2P, GON4L, AL139128.1, SYT11, U4, RIT1, KHDC4, SNORA80E, SCARNA4, SCARNA4, RXFP4, ARHGEF2, MIR6738, AL355388.1, ARHGEF2-AS1, AL355388.2, SSR2, UBQLN4, LAMTOR2, RAB25, MEX3A, LMNA, SEMA4A, AL135927.1.
- chr2:28,307,063–30,644,225, 42 genes, copy number 5–8: AC093690.1, RPL23AP34, FLJ31356, FOSL2, AC104695.3, AC104695.2, AC104695.1, PLB1, SNRPGP7, AC074011.1, RNA5SP89, AC092164.1, PPP1CB, SPDYA, AC097724.1, TRMT61B, WDR43, SNORD92, SNORD53, Y_RNA, SNORD53B, TOGARAM2, Y_RNA, PCARE, AC105398.1, CLIP4, ALK, AC074096.1, RN7SL516P, AC106870.3, AC106870.2, AC106870.1, AC016907.2, AC016907.1, YPEL5, SNORA10B, H3P5, LBH, AC109642.1, LINC01936, AC073255.1, LCLAT1.
- chr2:46,668,870–47,907,810, 33 genes, copy number 6: AC020604.1, LINC01118, SOCS5, LINC01119, AC016722.1, AC016722.2, MCFD2, TTC7A, AC093732.2, AC093732.1, STPG4, AC073283.3, AC073283.1, CALM2, EPCAM-DT, AC073283.2, BCYRN1, EPCAM, RN7SKP119, MIR559, Metazoa_SRP, MSH2, KCNK12, MSH2-OT1, AC079250.1, MSH6, NME2P2, AC006509.1, U6, FBXO11, RPL36AP15, RPS27AP7, AC079807.1.
- chr3:63,203,218–64,103,131, 19 genes, copy number 6: UBL5P3, SYNPR, SYNPR-AS1, RNA5SP134, SNTN, AC104162.1, C3orf49, THOC7, THOC7-AS1, ATXN7, SCAANT1, PSMD6-AS2, AC012557.1, PSMD6, PSMD6-AS1, AC012557.2, PRICKLE2-AS1, U3, LINC00994.
- chr3:72,202,944–73,624,941, 24 genes, copy number 5–6 (within-gene range 3–6): AC112219.1, AC134508.2, AC134508.1, RYBP, AC104435.2, RNU1-62P, AC104435.1, RNA5SP136, AC097369.4, SHQ1, AC134050.1, PSMD12P1, LAPTM4BP2, GXYLT2, Metazoa_SRP, FTH1P23, PPP4R2, RNU7-19P, EBLN2, RNU6-557P, RNU2-64P, CCDC75P1, RNU6-1270P, PDZRN3.
- chr3:124,723,788–125,681,453, 26 genes, copy number 5: AC022336.2, UMPS, MIR544B, AC022336.1, ITGB5, ITGB5-AS1, AC022336.3, 7SK, ENO1P3, MUC13, HEG1, RNA5SP137, AC117488.1, SLC12A8, RNU6-230P, MIR5092, ZNF148, DUTP1, DNAJB6P7, RNU6-232P, SNX4, Y_RNA, Y_RNA, OSBPL11, AF186996.3, AF186996.2.
- chr3:147,844,123–175,810,548, 415 genes, copy number 8–27 (within-gene range 3–27) (broad region; genes not listed).
- chr3:195,836,193–197,029,817, 61 genes, copy number 6–10 (broad region; genes not listed).
- chr6:31,142,439–31,969,751, 104 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr6:164,791,288–169,802,873, 110 genes, copy number 5–8 (broad region; genes not listed).
- chr7:99,408,641–100,041,689, 37 genes, copy number 5: BUD31, PTCD1, ATP5MF-PTCD1, CPSF4, AC073063.1, ATP5MF, ZNF789, ZNF394, ZKSCAN5, FAM200A, ZNF655, AC005020.2, TMEM225B, ZSCAN25, AC005020.1, CYP3A5, CYP3A7-CYP3A51P, CYP3A51P, CYP3A7, CYP3A4, AC069294.1, CYP3A137P, CYP3A43, AC011904.1, CYP3A52P, OR2AE1, TRIM4, GJC3, AC004522.3, Y_RNA, AC004522.1, AZGP1, AC004522.4, AZGP1P1, AC004522.2, AC004522.5, ZKSCAN1.
- chr7:105,301,522–106,838,480, 26 genes, copy number 5 (within-gene range 3–5): RWDD4P1, AC004884.2, RNU6-1322P, PUS7, AC073073.1, RINT1, EFCAB10, AC073073.2, YBX1P2, ATXN7L1, AC005099.1, CDHR3, AC004836.1, SYPL1, DCAF13P1, RNU6-392P, NAMPT, AC007032.1, LARP1BP2, AC004917.1, AC005050.3, AC005050.1, AC005050.2, CCDC71L, LINC02577, RNA5SP236.
- chr7:128,912,732–130,506,465, 55 genes, copy number 5–6: AC025594.1, IRF5, AC025594.2, TNPO3, RN7SL306P, ODCP, TPI1P2, AC018639.1, AC011005.2, AC011005.3, CYCSP20, AC011005.1, TSPAN33, RNY1P11, SMO, AC011005.4, AHCYL2, AC009244.1, CDC26P1, STRIP2, SNRPGP3, RNU1-72P, SMKR1, AC078846.1, NRF1, RNA5SP244, AC084864.2, MIR182, MIR96, MIR183, AC084864.1, UBE2H, AC073320.1, Y_RNA, ZC3HC1, RNA5SP245, KLHDC10, AC087071.1, TMEM209, AC087071.2, SSMEM1, AC024085.1, CPA2, CPA4, CPA5, CPA1, CEP41, AC007938.1, MESTIT1, MEST, AC007938.5, AC007938.6, AC007938.4, AC007938.2, MIR335.
- chr7:136,868,669–159,233,377, 557 genes, copy number 5–8 (broad region; genes not listed).
- chr8:42,374,063–101,224,573, 909 genes, copy number 5–7 (broad region; genes not listed).
- chr8:120,380,761–141,195,808, 266 genes, copy number 5–9 (broad region; genes not listed).
- chr10:69,088,103–69,692,452, 24 genes, copy number 5 (within-gene range 3–5): SRGN, Metazoa_SRP, VPS26A, RPS12P17, SUPV3L1, AL596223.1, HKDC1, AL596223.2, HK1, RPS15AP28, TACR2, ATP5MC1P7, TSPAN15, AC016821.1, TMEM256P1, NEUROG3, AL450311.1, MTATP6P23, MTCO2P23, MTCO1P23, MTND2P15, MTND1P20, FAM241B, LINC02651.
- chr10:77,433,572–79,067,895, 27 genes, copy number 5: COX6CP15, RNA5SP321, AL731556.1, AL731556.2, RNU6-1266P, IMPDH1P5, AL450306.1, DLG5, AL391421.1, RN7SL284P, DLG5-AS1, H2AZP5, Metazoa_SRP, POLR3A, RPS24, GNAI2P2, AL731555.1, AC012560.1, LINC00595, AC010163.3, AC010163.1, AC010163.2, SNORA71, AL583852.1, AC016820.1, ZMIZ1-AS1, AL356753.1.
- chr10:100,150,094–102,714,397, 88 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr11:62,169,293–63,048,126, 75 genes, copy number 5 (broad region; genes not listed).
- chr11:101,129,077–102,966,628, 42 genes, copy number 6–14: PGR-AS1, AP001533.1, TRPC6, MIR3920, AP003080.1, AP000776.1, ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27, MMP8, WTAPP1, AP000619.1, AP000619.3, MMP10, MMP1, AP000619.2, MMP3, MMP12, BOLA3P1, RNU7-159P, MMP13, AP001486.3.
- chr12:44,880,868–48,106,079, 78 genes, copy number 6–11 (broad region; genes not listed).
- chr14:76,761,468–90,185,853, 173 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr14:101,948,347–102,933,596, 24 genes, copy number 7: AL118558.3, AL118558.4, DYNC1H1, AL118558.2, AL118558.1, RN7SL472P, HSP90AA1, WDR20, MOK, ZNF839, CINP, TECPR2, RNU6-244P, ANKRD9, MIR4309, LINC02323, RN7SL546P, RCOR1, RPL23AP11, Y_RNA, AL132801.1, TRAF3, RNU6-1316P, AMN.
- chr17:3,510,502–4,268,430, 31 genes, copy number 6 (within-gene range 3–6): TRPV3, TRPV1, AC027796.5, AC027796.3, AC027796.1, SHPK, AC027796.2, CTNS, AC027796.4, TAX1BP3, P2RX5-TAX1BP3, AC132942.1, EMC6, P2RX5, ITGAE, AC116914.2, HASPIN, AC116914.1, NCBP3, CAMKK1, P2RX1, ATP2A3, LINC01975, ZZEF1, RNA5SP434, CYB5D2, ANKFY1, AC087292.1, Y_RNA, RYKP1, AC087742.1.
- chr17:6,853,861–7,711,372, 89 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr17:9,452,197–22,706,703, 490 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr17:36,210,924–37,406,836, 38 genes, copy number 5: CCL4L2, AC243829.5, AC243829.3, AC243829.6, TBC1D3I, AC233699.1, Y_RNA, TBC1D3G, TBC1D3H, RNU6-1192P, TBC1D3F, TBC1D3J, ZNHIT3, RNA5SP439, MYO19, PIGW, GGNBP2, AC243732.1, DHRS11, MRM1, AC243830.2, AC243830.3, AC243830.1, LHX1-DT, LHX1, AC243773.1, AATF, AC243773.2, AC244093.4, MIR2909, AC244093.3, AC244093.5, ACACA, AC244093.1, HMGB1P24, AC244093.2, C17orf78, AC243654.3.
- chr17:48,133,442–48,606,414, 19 genes, copy number 5 (within-gene range 2–5): SKAP1, MIR1203, SKAP1-AS1, RNU6-1152P, THRA1/BTR, AC036222.2, U3, AC036222.1, Y_RNA, HOXB1, HOXB2, HOXB-AS1, HOXB3, HOXB-AS3, HOXB-AS2, HOXB4, AC103702.1, MIR10A, HOXB5.
- chr17:67,377,281–68,763,882, 45 genes, copy number 6–9 (within-gene range 4–9): PITPNC1, Y_RNA, RN7SL756P, MIR548AA2, MIR548D2, AC110921.1, AC079331.2, AC079331.1, AC079331.3, NOL11, SNORA38B, RPSAP67, RPL17P41, BPTF, AC134407.1, AC134407.2, AC134407.3, RN7SL622P, C17orf58, KPNA2, FBXO36P1, AC145343.1, LINC00674, LRRC37A16P, AC005332.6, AC005332.3, AC005332.5, SH3GL1P3, RDM1P3, AC005332.7, AC005332.2, ARHGAP27P2, AC005332.4, AMZ2, AC005332.1, ARSG, SLC16A6, AC007780.1, WIPI1, MIR635, PRKAR1A, FAM20A, AC079210.1, LINC01482, AC011591.2.
- chr17:80,801,640–82,945,914, 141 genes, copy number 7–13 (within-gene range 1–13) (broad region; genes not listed).
- chr18:47,390–4,459,458, 100 genes, copy number 5 (broad region; genes not listed).
- chr19:44,326,555–44,889,223, 27 genes, copy number 5 (within-gene range 3–5): ZNF112, AC245748.1, ZNF285, AC245748.2, ZNF229, ZNF285B, ZNF180, CEACAM20, AC245748.3, CEACAM22P, AC243964.1, IGSF23, AC243964.3, PVR, MIR4531, CEACAM19, AC243964.4, CEACAM16, AC243964.2, BCL3, MIR8085, SNORA70, AC092066.1, CBLC, AC092306.1, BCAM, NECTIN2.
- chr19:47,968,046–48,944,969, 55 genes, copy number 5–8: BSPH1, ELSPBP1, CABP5, PLA2G4C, PLA2G4C-AS1, LIG1, AC011466.3, AC011466.2, ZSWIM9, CARD8, AC011466.4, AC011466.1, CARD8-AS1, ZNF114-AS1, ZNF114, CCDC114, EMP3, TMEM143, SYNGR4, KDELR1, GRIN2D, GRWD1, KCNJ14, AC008403.2, AC008403.1, CYTH2, LMTK3, AC008403.3, SULT2B1, FAM83E, SPACA4, RPL18, AC022154.1, SPHK2, DBP, CA11, SEC1P, NTN5, FUT2, MAMSTR, RASIP1, IZUMO1, FUT1, FGF21, RNU6-317P, BCAT2, AC026803.3, HSD17B14, PLEKHA4, PPP1R15A, TULP2, NUCB1, NUCB1-AS1, AC026803.1, DHDH.
- chr20:2,652,593–4,249,287, 63 genes, copy number 6 (broad region; genes not listed).
- chr20:31,721,507–32,585,074, 31 genes, copy number 6 (within-gene range 4–6): ABALON, TPX2, AL160175.1, MYLK2, FOXS1, DUSP15, TTLL9, RNU1-94P, PDRG1, XKR7, AL031658.2, AL031658.1, RNA5SP481, CCM2L, RNA5SP482, HCK, TM9SF4, AL049539.1, RSL24D1P6, TSPY26P, PLAGL2, POFUT1, MIR1825, AL121897.1, KIF3B, AL121583.1, ASXL1, NOL4L, AL034550.1, AL034550.3, AL034550.2.
- chr20:45,091,214–54,070,594, 235 genes, copy number 5–9 (broad region; genes not listed).
- chr22:18,906,238–20,070,965, 62 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 884. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
